Somatic mutation profile of tumor specimen TCGA-85-8353-01A (aliquot TCGA-85-8353-01A-21D-2293-08) from TCGA case TCGA-85-8353, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.7 years (26,549 days).
Specimen TCGA-85-8353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 619a48aa-88f3-4be8-92c8-76db41d7d5fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8353-10A (Blood Derived Normal), aliquot TCGA-85-8353-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ccf0fad-6f08-4c5c-96ce-0893c124a52a

The open-access MAF lists 191 somatic variants for this specimen: 148 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 39, Nonsense Mutation 9, Frame Shift Del 6, Intron 2, Splice Site 2, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 30/205 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 7/99 reads (7%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 46/160 reads (29%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1777A>T p.T593S (on ENST00000373993 / NM_138932.2; = p.T585S on NM_014576.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99255225; called by muse, mutect2, varscan2
- ADAM9 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV101122225; called by muse, mutect2, varscan2
- AGBL1 | c.641T>G p.L214W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101407825; called by muse, mutect2, varscan2
- AHCTF1 | c.1651G>T p.D551Y (on ENST00000366508; = p.D525Y on NM_015446.5) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100403089; called by muse, mutect2, varscan2
- ALAS2 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100237947; called by muse, mutect2, varscan2
- ALDH3A1 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855725; called by muse, mutect2, varscan2
- AQP5 | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV99527386; called by muse, mutect2, varscan2
- ARFGEF3 | c.4540C>T p.R1514W | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199637514, COSV52474553; called by muse, mutect2, varscan2
- ATP8A1 | c.3477G>C p.Q1159H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as COSV100044890, COSV52542368; called by muse, mutect2, varscan2
- ATRNL1 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100744123; called by muse, mutect2, varscan2
- BCORL1 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1292022115, COSV99498401; called by muse, mutect2, varscan2
- BMP5 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63705345; called by muse, mutect2, varscan2
- CDH10 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100049966; called by muse, mutect2, varscan2
- CEP350 | c.5369A>G p.K1790R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.362); catalogued as COSV100854293; called by muse, mutect2
- CFAP44 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868856; called by muse, mutect2, varscan2
- CFHR2 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.979); catalogued as COSV100804230; called by muse, mutect2, varscan2
- CHD2 | c.1377G>A p.K459= | Splice Region (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100560493; called by muse, mutect2
- CHIA | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.268); catalogued as rs771419256, COSV100588561, COSV100588711; called by muse, mutect2, varscan2
- CHIA | c.487C>A p.R163S (on ENST00000343320; = p.R55S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.836); catalogued as rs139158262, COSV100588563; called by muse, mutect2, varscan2
- CNTN3 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV99723210; called by muse, mutect2, varscan2
- CNTN3 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99723211; called by muse, mutect2, varscan2
- CNTN5 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs199945392, COSV99672679; called by muse, mutect2
- CNTNAP5 | c.2834G>A p.R945K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101443021; called by muse, mutect2, varscan2
- COL12A1 | c.2143G>T p.G715* | Nonsense Mutation (SNP) | VAF 44/243 reads (18%) | catalogued as COSV100485375; called by muse, mutect2, varscan2
- CS | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100673143; called by muse, mutect2, varscan2
- CTRB2 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs150266828; called by muse, mutect2, varscan2
- CYP11A1 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51430875, COSV99165888; called by muse, mutect2, varscan2
- CYP2A13 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs149632806; called by muse, mutect2, varscan2
- DCAF4L2 | c.892del p.D298Tfs*2 | Frame Shift Del (DEL) | VAF 28/127 reads (22%) | catalogued as COSV60481985; called by mutect2, pindel, varscan2
- DLL1 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100815911; called by muse, mutect2, varscan2
- DLX5 | c.764A>T p.N255I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99756210; called by muse, mutect2, varscan2
- DPP6 | c.398T>A p.V133E (on ENST00000377770 / NM_001364500.2; = p.V71E on NM_001936.5) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100122976; called by muse, mutect2, varscan2
- ELAVL2 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV99805375; called by muse, mutect2, varscan2
- ENTPD6 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as rs756830166, COSV100736968; called by muse, mutect2, varscan2
- EPHA8 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51272925, COSV99384177; called by muse, mutect2, varscan2
- FAM174B | c.368C>A p.T123K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776310212, COSV100526461; called by mutect2, varscan2
- FHL5 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99045125; called by muse, mutect2, varscan2
- FLG | c.6746G>C p.S2249T | Missense Mutation (SNP) | VAF 50/584 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV100910479, COSV64242009; called by muse, mutect2
- FMN2 | c.3998C>T p.S1333F | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142522; called by muse, mutect2, varscan2
- GAB1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.607); catalogued as COSV99527911; called by muse, mutect2, varscan2
- GAB1 | c.1520G>T p.R507M | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99527912; called by muse, mutect2, varscan2
- GRID2 | c.2062T>C p.Y688H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99937132; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2308G>T p.A770S (on ENST00000265755 / NM_016328.3; = p.A755S on NM_005685.4) | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV99733991; called by muse, mutect2, varscan2
- GUCA2B | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV101001746, COSV65368319; called by muse, mutect2, varscan2
- GUCA2B | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778790434, COSV101001747, COSV65368161; called by muse, mutect2, varscan2
- H2BC5 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV99175206; called by muse, mutect2, varscan2
- HEATR1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs993241928, COSV100857408; called by muse, mutect2, varscan2
- HERC2 | c.7774G>T p.G2592C | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870775; called by muse, mutect2, varscan2
- HRG | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV99214538; called by muse, mutect2, varscan2
- HTR7 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs751592867, COSV99518857, COSV99519712; called by muse, mutect2, varscan2
- ICA1L | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766859524, COSV64174394; called by muse, mutect2, varscan2
- IGFN1 | c.2088G>C p.E696D (on ENST00000295591 / NM_001367841.1; = p.E3153D on NM_001164586.2) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV55186468, COSV99811070; called by muse, mutect2, varscan2
- IKBKB | c.498C>A p.D166E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100645575; called by muse, mutect2, varscan2
- KBTBD6 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV101068690; called by muse, mutect2, varscan2
- KIF13B | c.654G>C p.E218D | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101580519; called by muse, mutect2, varscan2
- KIF19 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV100738921; called by muse, mutect2, varscan2
- KRTAP13-4 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as rs76547537, COSV61879152; called by muse, mutect2, varscan2
- KYNU | c.35C>G p.T12R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99932745; called by muse, mutect2, varscan2
- LRRFIP1 | c.842C>T p.T281I (on ENST00000392000 / NM_001137552.2; = p.T257I on NM_004735.4) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55250396; called by muse, mutect2
- LYAR | c.563A>T p.K188I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1006134560, COSV100603452; called by muse, mutect2, varscan2
- LYN | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1277517826, COSV101319566; called by muse, mutect2, varscan2
- MAGEB6 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV100983653; called by muse, mutect2, varscan2
- MANBAL | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101009421; called by muse, mutect2, varscan2
- MAPK15 | c.1423C>G p.R475G | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100567682, COSV100567805; called by muse, mutect2, varscan2
- MDH1B | c.22+1G>A p.X8_splice | Splice Site (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99378782; called by muse, mutect2
- MLXIP | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as COSV100038430; called by muse, mutect2, varscan2
- MS4A14 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868372829, COSV100279998; called by muse, mutect2, varscan2
- MYO10 | c.1230T>G p.F410L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101569764; called by muse, mutect2
- NCAM1 | c.1363C>A p.L455M (on ENST00000316851 / NM_181351.5; = p.L445M on NM_000615.7) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377000; called by muse, mutect2, varscan2
- NCKIPSD | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.889); catalogued as rs573286934, COSV99583685; called by muse, mutect2, varscan2
- NCOR1 | c.3461C>T p.S1154L | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99247024; called by muse, mutect2
- NCR1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as COSV99400743; called by muse, mutect2, varscan2
- NEXMIF | c.4546A>G p.I1516V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV99279564; called by muse, mutect2, varscan2
- NF1 | c.1655T>G p.L552R | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555613193, COSV100645994, COSV62197265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP11 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789623; called by muse, mutect2, varscan2
- NLRP11 | c.2626G>T p.G876* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100789625; called by muse, mutect2, varscan2
- NOTCH3 | c.1379-2A>T p.X460_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99655764; called by muse, mutect2
- NPR2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61309291; called by muse, mutect2, varscan2
- NTNG1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV64269214; called by muse, mutect2, varscan2
- NTNG2 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs779813862, COSV62369617; called by muse, mutect2, varscan2
- OGFRL1 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100965713; called by muse, mutect2, varscan2
- OR11H6 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100209700; called by muse, mutect2
- OR2H1 | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101009777; called by muse, mutect2, varscan2
- OR2M3 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 142/550 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV101513393; called by muse, mutect2, varscan2
- OR2T12 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV58779699; called by muse, mutect2, varscan2
- OR2T12 | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.009); catalogued as rs139536610, COSV100527524; called by muse, mutect2, varscan2
- OR51F2 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1484244867, COSV100437880; called by muse, mutect2, varscan2
- OR5M1 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV101591529; called by muse, mutect2, varscan2
- P2RY8 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV101183931; called by muse, mutect2, varscan2
- PBX3 | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100655221, COSV100655261; called by muse, mutect2, varscan2
- PCDHGA12 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1432933024, COSV52743408; called by muse, mutect2, varscan2
- PEG10 | c.570G>T p.M190I (on ENST00000482108 / NM_001040152.2; = p.M224I on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV101509844; called by muse, mutect2, varscan2
- PHEX | c.1781A>G p.D594G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV101039383; called by muse, mutect2, varscan2
- PHIP | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1044058522, COSV51502524; called by muse, mutect2, varscan2
- PKHD1L1 | c.10551G>T p.M3517I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV101005309, COSV65744001; called by muse, mutect2, varscan2
- POTEE | c.84C>A p.C28* | Nonsense Mutation (SNP) | VAF 36/399 reads (9%) | catalogued as COSV100386885, COSV100388818; called by muse, mutect2
- PRDM9 | c.315del p.W105* | Frame Shift Del (DEL) | VAF 32/251 reads (13%) | catalogued as COSV99691607; called by mutect2, pindel*, varscan2
- PRRT3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99926291; called by muse, mutect2, varscan2
- PSAT1 | c.985A>C p.M329L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.149); catalogued as COSV100716492; called by muse, mutect2, varscan2
- PTPRG | c.326A>T p.N109I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99872761; called by muse, mutect2, varscan2
- RADIL | c.1690C>A p.L564M | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV101271246, COSV68201394; called by muse, mutect2, varscan2
- RASIP1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99710462; called by muse, mutect2, varscan2
- RD3 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100879189; called by muse, mutect2, varscan2
- RGL4 | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV99318623; called by muse, mutect2
- RIMS1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV99323916; called by muse, mutect2, varscan2
- RNF2 | c.841A>C p.M281L | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100835656; called by muse, mutect2, varscan2
- RNF24 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100270643; called by muse, mutect2, varscan2
- RP1 | c.5829T>G p.I1943M | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99606226; called by muse, mutect2
- RSRC2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100063307; called by muse, mutect2, varscan2
- RTF2 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99196455; called by muse, mutect2, varscan2
- SAMD15 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs767225534, COSV99374754; called by muse, mutect2, varscan2
- SARDH | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100897871; called by muse, mutect2, varscan2
- SC5D | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs142234975; called by muse, mutect2, varscan2
- SCN10A | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV101479234; called by muse, mutect2, varscan2
- SEMA5B | c.2721C>A p.C907* | Nonsense Mutation (SNP) | VAF 65/202 reads (32%) | catalogued as COSV99530777; called by muse, mutect2, varscan2
- SH3PXD2B | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100287648; called by muse, mutect2, varscan2
- SHOX2 | c.428G>A p.S143N (on ENST00000441443 / NM_006884.3; = p.S167N on NM_003030.4) | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101273739; called by muse, mutect2, varscan2
- SLC17A8 | c.456C>A p.N152K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100035167; called by muse, mutect2, varscan2
- SLCO1C1 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56868760, COSV99858447; called by muse, mutect2, varscan2
- SLCO2A1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100188639; called by muse, mutect2, varscan2
- SMG7 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs764737499, COSV100750058; called by muse, mutect2, varscan2
- SPATA22 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99279086; called by muse, mutect2, varscan2
- SPHKAP | c.2332C>T p.H778Y | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100763667; called by muse, mutect2, varscan2
- SPINK14 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100810968; called by muse, mutect2, varscan2
- SUN5 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100644770; called by muse, mutect2, varscan2
- SVEP1 | c.3226A>G p.T1076A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as COSV100237110; called by mutect2, varscan2
- SZT2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV100161554; called by muse, mutect2, varscan2
- TLN2 | c.4345G>T p.V1449F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1567531382, COSV60890998; called by muse, mutect2, varscan2
- TM2D2 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs1256086064, COSV101165973; called by muse, mutect2, varscan2
- TMEM81 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99196739, COSV99196826; called by muse, mutect2, varscan2
- TPRG1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 10/181 reads (6%) | catalogued as COSV100800172; called by muse, mutect2
- TPRG1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV100800173; called by muse, mutect2
- TRDN | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100520826; called by muse, mutect2, varscan2
- TTN | c.23912A>T p.D7971V (on ENST00000591111; = p.D7044V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | PolyPhen benign (0.023); catalogued as COSV100593377; called by muse, mutect2, varscan2
- WDR64 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100843644; called by muse, mutect2, varscan2
- WNK2 | c.2422G>T p.A808S | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV99940877; called by muse, mutect2, varscan2
- WSCD1 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 189/506 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100496365; called by muse, mutect2, varscan2
- XIRP2 | c.1025A>T p.Y342F (on ENST00000628543; = p.Y517F on NM_152381.6) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.31); catalogued as COSV99738246; called by muse, mutect2, varscan2
- ZGPAT | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100157391; called by muse, mutect2, varscan2
- ZNF514 | c.922A>T p.R308W | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727569; called by muse, mutect2, varscan2
- AMBN | c.1326del p.W442Cfs*43 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- RB1 | c.1273del p.I425Sfs*32 | Frame Shift Del (DEL) | VAF 30/125 reads (24%) | called by mutect2, pindel, varscan2
- SLC47A2 | c.604_607del p.S202Tfs*39 | Frame Shift Del (DEL) | VAF 89/465 reads (19%) | called by pindel, varscan2
- TBC1D9 | c.3785C>T p.S1262L | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2
- UTRN | c.7652+1del | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ADAM9 | c.2088G>A p.R696= | Silent (SNP) | VAF 58/214 reads (27%) | catalogued as COSV101165974; called by muse, mutect2, varscan2
- ASMT | c.636A>G p.P212= (on ENST00000381229; = p.P240= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/395 reads (18%) | catalogued as COSV101172404; called by muse, mutect2, varscan2
- BRIP1 | c.372T>C p.T124= | Silent (SNP) | VAF 50/266 reads (19%) | catalogued as rs1555617785, COSV99369238; ClinVar: likely benign; called by muse, mutect2, varscan2
- CFAP47 | c.2619T>A p.V873= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as COSV99934349; called by muse, mutect2, varscan2
- CHRM1 | c.108G>A p.S36= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs542128793, COSV100186084; called by muse, mutect2, varscan2
- CNTLN | c.3249A>G p.S1083= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV99262683; called by muse, mutect2, varscan2
- CUX2 | c.981G>A p.L327= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99918571; called by muse, mutect2, varscan2
- DPYSL3 | c.531T>C p.S177= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100574881; called by muse, mutect2, varscan2
- EPPK1 | c.5958G>T p.T1986= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV101599730; called by muse, mutect2
- FAM78A | c.528C>T p.N176= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as rs774286163, COSV55992611; called by muse, mutect2, varscan2
- FGD5 | c.3528A>G p.L1176= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV99547201; called by muse, mutect2, varscan2
- GJA8 | c.609C>A p.T203= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV53789693; called by muse, mutect2, varscan2
- HCN1 | c.1083T>C p.Y361= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV100298481; called by muse, mutect2, varscan2
- HEATR1 | c.3178C>T p.L1060= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs773380550, COSV100857407; called by muse, mutect2, varscan2
- ICE1 | c.2430A>G p.E810= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99663695; called by muse, mutect2
- INTS12 | c.1065G>T p.T355= | Silent (SNP) | VAF 15/229 reads (7%) | catalogued as rs769128380, COSV100415663; called by muse, mutect2
- ITIH2 | c.951G>A p.V317= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100623151; called by muse, mutect2, varscan2
- LTBP4 | c.2436G>T p.S812= (on ENST00000308370 / NM_001042544.1; = p.S775= on NM_003573.2) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99180377; called by muse, mutect2, varscan2
- MAGEB1 | c.55C>A p.R19= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100974834; called by muse, mutect2
- MMP16 | c.444T>A p.T148= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV99685929; called by muse, mutect2
- MUC5B | c.10600A>C p.R3534= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV101500020; called by muse, mutect2, varscan2
- NCAM2 | c.1353T>A p.T451= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as COSV53080797; called by muse, mutect2, varscan2
- NRG2 | c.996C>T p.S332= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99179903; called by muse, mutect2, varscan2
- OR2L13 | c.129C>A p.A43= | Silent (SNP) | VAF 50/232 reads (22%) | catalogued as COSV100813658; called by muse, mutect2, varscan2
- PGRMC2 | c.621A>G p.P207= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs1258532443, COSV99600903; called by muse, mutect2, varscan2
- PRKDC | c.11529G>A p.L3843= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100038317; called by muse, mutect2
- RSAD2 | c.624G>A p.R208= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV101149745; called by muse, mutect2, varscan2
- SCAP | c.555C>T p.F185= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV99652388; called by muse, mutect2, varscan2
- SCN2A | c.4200T>C p.N1400= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs780902406, COSV99330036; called by muse, mutect2, varscan2
- SECISBP2L | c.633T>A p.I211= | Silent (SNP) | VAF 76/357 reads (21%) | catalogued as COSV99959829; called by muse, mutect2, varscan2
- SLC11A1 | c.750C>T p.A250= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99261850; called by muse, mutect2
- SLC32A1 | c.963C>A p.I321= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV54146997, COSV54148571, COSV99461750; called by muse, mutect2, varscan2
- SOBP | c.2445C>G p.A815= | Silent (SNP) | VAF 42/258 reads (16%) | catalogued as COSV100432756; called by muse, mutect2, varscan2
- TBC1D32 | c.2721A>G p.P907= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as rs755115001, COSV99249472; called by muse, mutect2, varscan2
- TRIP12 | c.4404A>G p.S1468= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as COSV99389278; called by muse, mutect2
- TTN | c.51195C>A p.A17065= (on ENST00000591111; = p.A9641= on NM_003319.4) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100593375, COSV100632445; called by muse, mutect2, varscan2
- VIRMA | c.2703T>C p.L901= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as rs1199431170, COSV99887554; called by muse, mutect2, varscan2
- XRN2 | c.90T>C p.N30= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV101017940; called by muse, mutect2, varscan2
- ZKSCAN8 | c.369G>A p.V123= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100362809; called by muse, mutect2, varscan2
- EPDR1 | c.-196_-181del | 5'UTR (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- PTGER3 | c.*24-12852A>G | Intron (SNP) | VAF 33/135 reads (24%) | catalogued as rs750090717; called by muse, mutect2, varscan2
- TPH2 | c.*1T>A | 3'UTR (SNP) | VAF 53/432 reads (12%) | catalogued as COSV100421877; called by muse, mutect2, varscan2
- TTN | c.10303+1169C>A | Intron (SNP) | VAF 27/259 reads (10%) | catalogued as COSV100593379; called by muse, mutect2, varscan2
